Somatic mutation profile of tumor specimen TCGA-DD-A3A9-01A (aliquot TCGA-DD-A3A9-01A-11D-A25V-10) from TCGA case TCGA-DD-A3A9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 64.4 years (23,526 days).
Specimen TCGA-DD-A3A9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb1073d7-89d9-4d18-a2ae-a2a97bccf694.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A9-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A9-11A-11D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23c7812d-b3c4-4e3e-aaa1-6f2811ac1f5a

The open-access MAF lists 446 somatic variants for this specimen: 301 protein-altering or splice-affecting, 111 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 271, Silent 111, Nonsense Mutation 13, Intron 12, 3'UTR 12, Splice Site 7, Frame Shift Del 7, 5'UTR 5, RNA 5, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.7180C>T p.R2394* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as rs397515848, CM993162, COSV57312880; ClinVar: pathogenic; called by muse, mutect2
- ABCA4 | c.4357T>A p.Y1453N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.424); catalogued as COSV64678999; called by muse, mutect2
- ABCA9 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV60628006; called by muse, mutect2, varscan2
- ABCC8 | c.2072A>T p.D691V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV56858743; called by mutect2, varscan2
- AC132217.2 | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV56102130; called by muse, mutect2, varscan2
- ACBD5 | c.1594A>T p.K532* (on ENST00000375888 / NM_001352568.1; = p.K523* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 98/243 reads (40%) | catalogued as COSV65521600; called by muse, mutect2, varscan2
- ACTR10 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs372667907; called by muse, mutect2, varscan2
- ADAMTS18 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1453207988, COSV51424071; called by muse, mutect2, varscan2
- ADAMTS9 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.329); catalogued as rs1176731012, COSV55792243; called by muse, mutect2, varscan2
- ADCY2 | c.1910T>C p.L637P | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV57904229; called by muse, mutect2, varscan2
- ADGRL3 | c.2160T>A p.N720K (on ENST00000506720 / NM_001322402.2; = p.N652K on NM_015236.6) | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV72232140; called by muse, mutect2, varscan2
- ADORA2B | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 101/159 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203760263, COSV58483772; called by muse, mutect2, varscan2
- AHNAK | c.11408A>G p.K3803R | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57233909; called by muse, mutect2, varscan2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, mutect2
- AL645922.1 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54962909; called by muse, mutect2, varscan2
- AL713999.2 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 16/281 reads (6%) | catalogued as COSV55280544; called by muse, mutect2
- ALG9 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV52791420; called by muse, mutect2, varscan2
- AMER2 | c.1832G>C p.S611T | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63440699; called by muse, mutect2, varscan2
- ANKRD12 | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV50854546; called by muse, mutect2, varscan2
- AP3B1 | c.2227A>G p.N743D | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV54894664; called by muse, mutect2, varscan2
- ARFGEF3 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 36/340 reads (11%) | catalogued as COSV52472599; called by muse, mutect2, varscan2
- ARL13A | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65880397; called by muse, mutect2, varscan2
- ASCC3 | c.6082A>T p.N2028Y | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV64981911; called by muse, mutect2, varscan2
- BICD1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55689507; called by muse, mutect2
- BLID | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV101601715, COSV73340198, COSV73340423; called by muse, mutect2, varscan2
- BMPR1A | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63135450; called by muse, mutect2, varscan2
- C10orf53 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1224305468, COSV65107612; called by muse, mutect2
- C1orf116 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63944027; called by muse, mutect2
- C6orf118 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs757080711, COSV57812959; called by muse, mutect2, varscan2
- CCDC110 | c.2495A>T p.H832L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.017); catalogued as rs763280862, COSV56873713; called by muse, mutect2, varscan2
- CCDC136 | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV52806090; called by muse, mutect2, varscan2
- CCDC150 | c.352A>T p.I118F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV55879415; called by muse, mutect2, varscan2
- CCDC185 | c.556T>A p.S186T | Missense Mutation (SNP) | VAF 47/443 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); catalogued as COSV64822083; called by muse, mutect2, varscan2
- CCDC191 | c.2157G>T p.K719N | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV55677062; called by muse, mutect2, varscan2
- CCNB3 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV52080675; called by muse, mutect2, varscan2
- CCR7 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV55850993; called by muse, mutect2, varscan2
- CCSER2 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.189); catalogued as COSV56513576; called by muse, mutect2, varscan2
- CDA | c.267-1G>A p.X89_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | catalogued as COSV66752528; called by muse, mutect2, varscan2
- CDHR1 | c.1873del p.H625Tfs*30 | Frame Shift Del (DEL) | VAF 45/163 reads (28%) | catalogued as COSV60559526; called by mutect2, pindel, varscan2
- CELSR3 | c.3015T>A p.D1005E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51170700; called by muse, mutect2, varscan2
- CHD1 | c.3364A>G p.N1122D | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.306); catalogued as COSV52345323; called by muse, mutect2, varscan2
- CMKLR1 | c.21T>A p.D7E (on ENST00000312143 / NM_001142344.2; = p.D5E on NM_004072.3) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56442447; called by muse, mutect2
- COL12A1 | c.2489T>C p.M830T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV59409818; called by muse, mutect2, varscan2
- COL27A1 | c.2351G>A p.G784D | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61931345; called by muse, mutect2, varscan2
- COL5A2 | c.4094A>T p.D1365V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV66416141; called by muse, mutect2, varscan2
- COL6A3 | c.5621G>C p.R1874T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV55113691, COSV99797060; called by muse, mutect2, varscan2
- COMMD9 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 160/319 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs1037839504, COSV54672838; called by muse, mutect2, varscan2
- CPNE5 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV55200655; called by muse, mutect2, varscan2
- CRYBG1 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV64815014; called by muse, mutect2, varscan2
- CTNNA1 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 36/283 reads (13%) | catalogued as COSV57082345; called by muse, mutect2, varscan2
- CUBN | c.6584T>A p.F2195Y | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64728982; called by muse, mutect2, varscan2
- CYLC1 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61412343; called by muse, mutect2, varscan2
- DDX46 | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62801304; called by muse, mutect2, varscan2
- DGKK | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65709612; called by muse, mutect2, varscan2
- DLG2 | c.42+2T>A p.X14_splice | Splice Site (SNP) | VAF 17/131 reads (13%) | catalogued as rs775634344, COSV65881156; called by muse, mutect2, varscan2
- DMRT3 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 18/129 reads (14%) | catalogued as COSV51909075; called by muse, mutect2, varscan2
- DNAH2 | c.9872C>T p.A3291V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs770700071, COSV66726805; called by muse, mutect2, varscan2
- DNAH5 | c.13813A>G p.T4605A | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54256709; called by muse, mutect2, varscan2
- DNAI2 | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 81/120 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56763033; called by muse, mutect2, varscan2
- DNAJB8 | c.536T>G p.F179C | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV59879760; called by muse, mutect2, varscan2
- DOCK11 | c.3386A>G p.D1129G | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs112023398, COSV52248861; called by muse, mutect2, varscan2
- DOCK2 | c.4964G>A p.C1655Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV56992683; called by muse, mutect2, varscan2
- DUSP7 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as COSV56589902; called by muse, mutect2, varscan2
- DYNC1I1 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV61472776; called by muse, mutect2, varscan2
- EBF1 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV58196511, COSV58197395; called by muse, mutect2, varscan2
- ECHS1 | c.730G>C p.V244L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV63907605; called by muse, mutect2, varscan2
- EDRF1 | c.2728A>G p.M910V (on ENST00000356792 / NM_001202438.2; = p.M876V on NM_015608.2) | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs772234625, COSV61766602; called by muse, mutect2, varscan2
- EFEMP1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62615998, COSV62618216; called by muse, mutect2, varscan2
- EIF3D | c.218A>G p.H73R | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53405726; called by muse, mutect2, varscan2
- EIF4E1B | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV53782259; called by muse, mutect2, varscan2
- ELL | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53216359; called by muse, mutect2, varscan2
- ELOA2 | c.1113T>A p.D371E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.12); catalogued as COSV55309994; called by muse, mutect2, varscan2
- EML5 | c.980A>T p.E327V | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61352476; called by muse, mutect2, varscan2
- ESRRG | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 58/649 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV63184097; called by muse, mutect2
- FAM114A1 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62675312; called by muse, mutect2, varscan2
- FAM133A | c.401A>G p.K134R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); catalogued as COSV59078005; called by muse, mutect2, varscan2
- FAM81B | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV51980413, COSV51987400; called by muse, mutect2, varscan2
- FHAD1 | c.2532A>T p.L844F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58991043; called by muse, mutect2, varscan2
- FLG2 | c.2939G>C p.G980A | Missense Mutation (SNP) | VAF 38/509 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV66174223; called by muse, mutect2
- FLNA | c.6442C>A p.R2148S (on ENST00000369850 / NM_001110556.2; = p.R2140S on NM_001456.3) | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV61052999; called by muse, mutect2, varscan2
- FNDC3B | c.1465A>T p.T489S | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as COSV61050938; called by muse, mutect2, varscan2
- FOLR1 | c.95A>C p.E32A | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV56617302; called by muse, mutect2, varscan2
- FOXC1 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769646390, COSV66515985, COSV66516814; called by muse, mutect2
- FOXO4 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs367715683, COSV58576572; called by muse, mutect2, varscan2
- FREM1 | c.1981A>T p.I661L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV66531418; called by muse, mutect2, varscan2
- FXN | c.86A>G p.D29G (on ENST00000377270; = p.D104G on NM_000144.5) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV66010578; called by muse, mutect2, varscan2
- GALNT14 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61112013; called by muse, mutect2, varscan2
- GNB4 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV51712138; called by muse, mutect2, varscan2
- GNL2 | c.1988G>A p.R663K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56171705; called by muse, mutect2, varscan2
- GNPAT | c.1938-2A>G p.X646_splice | Splice Site (SNP) | VAF 32/340 reads (9%) | catalogued as COSV64154512; called by muse, mutect2
- GPC1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs767152299; called by muse, varscan2
- GPR158 | c.3108G>T p.M1036I | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV66275282, COSV66284720; called by muse, mutect2, varscan2
- GPR31 | c.524T>A p.I175N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV64762090; called by muse, mutect2
- GRAMD4 | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63033046; called by muse, mutect2, varscan2
- GRIA2 | c.1537T>A p.S513T | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.444); catalogued as COSV52408754; called by muse, mutect2, varscan2
- GRK7 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV53825788; called by muse, mutect2, varscan2
- GZMK | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV50249276; called by muse, mutect2, varscan2
- HEXA | c.611A>T p.H204L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM930394, COSV51509253; called by muse, mutect2, varscan2
- HMCN1 | c.13216A>T p.I4406F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54946960; called by muse, mutect2, varscan2
- HMGB4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as rs769598918, COSV53907834; called by muse, mutect2, varscan2
- HTR1D | c.842T>A p.L281H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV58449605; called by muse, mutect2, varscan2
- HUWE1 | c.12478C>G p.L4160V | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV53366471; called by muse, mutect2, varscan2
- IFIT2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV51081007; called by muse, mutect2
- IFRD1 | c.797+1G>A p.X266_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | catalogued as rs778041377, COSV50045568; called by muse, mutect2, varscan2
- IGKV5-2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs761673271; called by muse, mutect2, varscan2
- IGSF9 | c.1343C>T p.P448L (on ENST00000368094 / NM_001135050.2; = p.P432L on NM_020789.4) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63642971; called by muse, mutect2
- IKZF2 | c.1048G>C p.V350L | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV59584988; called by muse, mutect2, varscan2
- IL12RB1 | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59099872; called by muse, mutect2, varscan2
- IQGAP1 | c.4910A>C p.D1637A | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV51592161; called by muse, mutect2
- IRAK1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV57657671; called by muse, mutect2, varscan2
- KCNH1 | c.1374G>T p.M458I (on ENST00000271751 / NM_172362.3; = p.M431I on NM_002238.4) | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV55107950; called by muse, mutect2
- KCNH7 | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV59816427; called by muse, mutect2, varscan2
- KCNS3 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV58409137; called by muse, mutect2
- KCTD16 | c.870C>G p.C290W | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV72580848; called by muse, mutect2, varscan2
- KCTD20 | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs765194359, COSV54805172; called by muse, mutect2, varscan2
- KLHL29 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490082776, COSV56026577; called by muse, mutect2, varscan2
- KMT2A | c.8173G>A p.E2725K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV63293384; called by muse, mutect2, varscan2
- KNL1 | c.5480A>G p.D1827G (on ENST00000346991 / NM_170589.5; = p.D1801G on NM_144508.5) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV61161177; called by muse, mutect2, varscan2
- KPNA2 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57859134; called by muse, mutect2, varscan2
- KRT27 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1323211995, COSV56973708; called by muse, mutect2
- LGSN | c.880A>T p.R294W | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV65728884; called by muse, mutect2, varscan2
- LIPI | c.20A>G p.H7R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); catalogued as rs773619059, COSV60716710; called by muse, mutect2, varscan2
- LRRC1 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs200563845, COSV63831105; called by muse, mutect2, varscan2
- LRRC3B | c.127T>G p.S43A | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV67522926; called by muse, mutect2, varscan2
- LTBP4 | c.4048G>C p.V1350L (on ENST00000308370 / NM_001042544.1; = p.V1313L on NM_003573.2) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.501); catalogued as COSV52591936; called by muse, mutect2, varscan2
- MADD | c.3497G>A p.S1166N | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs375878509; called by muse, mutect2, varscan2
- MAMLD1 | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as COSV53381671; called by muse, mutect2, varscan2
- MAP3K9 | c.1635C>G p.S545R | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV67123131; called by muse, mutect2, varscan2
- MCCC1 | c.742A>T p.K248* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | catalogued as COSV55612390; called by muse, mutect2, varscan2
- MCTP1 | c.2609A>T p.K870M | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56535842; called by muse, mutect2, varscan2
- MDGA1 | c.2618A>G p.N873S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV51802616; called by muse, mutect2
- MDGA1 | c.2531A>G p.H844R | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51802639; called by muse, mutect2
- MEGF8 | c.4213G>A p.A1405T (on ENST00000251268 / NM_001271938.2; = p.A1338T on NM_001410.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.48); catalogued as COSV52097021; called by muse, mutect2, varscan2
- MFSD11 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV60629293; called by muse, mutect2, varscan2
- MIA3 | c.3628C>T p.Q1210* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV60518836; called by muse, mutect2, varscan2
- MIER1 | c.709G>A p.D237N (on ENST00000355356 / NM_001077701.3; = p.D254N on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.385); catalogued as COSV62532591; called by muse, mutect2
- MLKL | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58206827; called by muse, mutect2, varscan2
- MORC1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51733042; called by muse, mutect2, varscan2
- MORC4 | c.2509G>T p.A837S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV55247256, COSV99717627; called by muse, mutect2, varscan2
- MOSPD2 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66860985; called by muse, mutect2, varscan2
- MTNR1A | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV56158232; called by muse, mutect2, varscan2
- MUC16 | c.31735A>G p.R10579G | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV67499380; called by muse, mutect2, varscan2
- MUC16 | c.31001C>T p.S10334F | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as COSV67457269; called by muse, mutect2, varscan2
- MUC2 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs555224884; called by muse, mutect2, varscan2
- MUSK | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.951); catalogued as COSV51898632; called by muse, mutect2, varscan2
- MYLIP | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100785942; called by muse, mutect2
- MYOCD | c.2414A>G p.E805G | Missense Mutation (SNP) | VAF 114/177 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58513711; called by muse, mutect2, varscan2
- NAF1 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1359592816, COSV56806457; called by muse, mutect2, varscan2
- NAV1 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55227633; called by muse, mutect2
- NBAS | c.6916A>T p.T2306S | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as COSV55740148; called by muse, mutect2
- NEK10 | c.3349A>G p.N1117D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368155143; called by muse, mutect2, varscan2
- NES | c.4569G>A p.M1523I | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63963270; called by muse, mutect2, varscan2
- NES | c.2680T>A p.S894T | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV63963272; called by muse, mutect2
- NEU1 | c.847A>G p.N283D | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); catalogued as COSV57669444; called by muse, mutect2, varscan2
- NLRP4 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV56724805; called by muse, mutect2, varscan2
- NLRP7 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs142163492; called by muse, mutect2, varscan2
- NMUR2 | c.875G>C p.S292T | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54923337; called by muse, mutect2, varscan2
- NPAP1 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.783); catalogued as COSV61510142, COSV61512194; called by muse, mutect2, varscan2
- NPR1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs561449958, COSV64140168; called by muse, mutect2, varscan2
- NR6A1 | c.1443A>G p.*481Wext*66 (on ENST00000487099 / NM_033334.4; = p.*476Wext*66 on NM_001489.5) | Nonstop Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV60638995; called by muse, mutect2, varscan2
- NRSN1 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs765575803, COSV65894750; called by muse, mutect2, varscan2
- NUP214 | c.2723G>A p.S908N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV63913591; called by muse, mutect2, varscan2
- NUP93 | c.2123A>T p.D708V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV57434647; called by muse, mutect2, varscan2
- ONECUT3 | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66640741; called by muse, mutect2, varscan2
- OPN4 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54120490; called by muse, mutect2, varscan2
- OR13C3 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV66166407; called by muse, mutect2, varscan2
- OR2G6 | c.488C>A p.T163N | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58576057; called by muse, mutect2
- OR2L2 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV63562595; called by muse, mutect2
- OR2T1 | c.175T>A p.Y59N | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63543037; called by muse, mutect2
- OR2T34 | c.384T>G p.Y128* | Nonsense Mutation (SNP) | VAF 78/984 reads (8%) | catalogued as COSV60902219; called by muse, mutect2
- OR5D18 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV61736021; called by muse, mutect2, varscan2
- OR7C2 | c.24A>T p.E8D | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.019); catalogued as COSV50182375; called by muse, mutect2
- OSTM1 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51972053; called by muse, mutect2, varscan2
- PABPC1L | c.1702C>G p.L568V | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53843513; called by muse, mutect2, varscan2
- PCDH11X | c.2622G>C p.K874N | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV53475312, COSV53511029, COSV53513988; called by muse, mutect2, varscan2
- PCDH15 | c.3953A>G p.N1318S | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV57406267; called by muse, mutect2, varscan2
- PCDHAC2 | c.2371T>A p.Y791N | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1326685727, COSV53873523, COSV99145855; called by muse, mutect2, varscan2
- PCDHB1 | c.1547C>A p.A516E | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60630920, COSV60633681; called by muse, mutect2, varscan2
- PCDHGA1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV65300286; called by muse, mutect2, varscan2
- PCNT | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs1301050198, COSV64033735; called by muse, mutect2, varscan2
- PELP1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as rs770325846, COSV52593069; called by muse, mutect2, varscan2
- PELP1 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.239); catalogued as COSV52593085; called by muse, mutect2, varscan2
- PHRF1 | c.4875C>A p.D1625E (on ENST00000264555 / NM_001286581.2; = p.D1624E on NM_020901.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV52763877; called by muse, mutect2, varscan2
- PIK3C2G | c.2251C>T p.H751Y (on ENST00000676171; = p.H710Y on NM_004570.5) | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1469213191, COSV56837458; called by muse, mutect2
- PKD1L1 | c.2300G>A p.S767N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56968229, COSV56980072; called by muse, mutect2
- PKHD1 | c.10048A>G p.R3350G | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV61897432; called by muse, mutect2, varscan2
- PLA2G4A | c.494T>A p.I165K | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV66557548; called by muse, mutect2
- PLBD1 | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53696851; called by muse, mutect2
- PRAMEF2 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53575392, COSV53579998; called by muse, mutect2, varscan2
- PRKAB2 | c.601A>G p.R201G | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV54214394, COSV54214868; called by muse, mutect2
- PROS1 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as CM128585, COSV62398147, COSV62399835; called by muse, mutect2, varscan2
- PSD2 | c.1971G>A p.E657= | Splice Region (SNP) | VAF 16/148 reads (11%) | catalogued as COSV51199111, COSV51214356; called by muse, mutect2, varscan2
- PTPRO | c.559T>A p.Y187N | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55524630; called by muse, mutect2, varscan2
- RAB3GAP2 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52967607; called by muse, mutect2
- RAG1 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 38/195 reads (19%) | catalogued as COSV55028938; called by muse, mutect2, varscan2
- RAG2 | c.1260C>A p.C420* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV57559361, COSV57560146; called by muse, mutect2, varscan2
- RAI2 | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV100518182, COSV58966550; called by muse, mutect2, varscan2
- RBM14 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59560659; called by muse, mutect2
- RFX6 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV60589323; called by muse, mutect2
- RFX7 | c.238A>G p.S80G (on ENST00000559447 / NM_001368074.1; = p.S177G on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV57969487; called by muse, mutect2, varscan2
- RGPD4 | c.4777T>A p.S1593T | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV61745221, COSV61750171; called by muse, mutect2, varscan2
- RGS7 | c.1321T>A p.S441T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58563504; called by muse, mutect2
- RGS8 | c.233T>C p.F78S (on ENST00000367556 / NM_001369564.2; = p.F96S on NM_033345.3) | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51121080; called by muse, mutect2
- RIPOR3 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV50408132; called by muse, mutect2, varscan2
- RNF17 | c.4571T>A p.L1524Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55053207; called by muse, mutect2, varscan2
- RPAP2 | c.1268G>A p.W423* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs1489823796, COSV72509703; called by muse, mutect2, varscan2
- RRBP1 | c.2449G>T p.E817* (on ENST00000377813 / NM_001365613.2; = p.E384* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV55709596; called by muse, mutect2, varscan2
- RSPH9 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.472); catalogued as COSV64665936; called by muse, mutect2
- RTL1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV66017598; called by muse, mutect2, varscan2
- RTN1 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50754204; called by muse, mutect2, varscan2
- RUFY4 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV60249753; called by muse, mutect2, varscan2
- RYR2 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.675); catalogued as rs1384422533, COSV63719055; called by muse, mutect2, varscan2
- RYR2 | c.14582T>C p.I4861T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63719067; called by muse, mutect2
- SCLY | c.577C>A p.R193S (on ENST00000651534; = p.R185S on NM_016510.7) | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV54545040; called by muse, mutect2, varscan2
- SEC14L4 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV55401853; called by muse, mutect2, varscan2
- SEL1L | c.1365G>T p.M455I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV60920468; called by muse, mutect2, varscan2
- SEMA3C | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54857304; called by muse, mutect2, varscan2
- SEMA6A | c.1650-1G>C p.X550_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV56712404, COSV56715495; called by muse, mutect2
- SFXN1 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58495447; called by muse, mutect2, varscan2
- SHROOM4 | c.3778T>C p.F1260L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1345847842, COSV56798402; called by muse, mutect2, varscan2
- SIGLEC11 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772560355, COSV70222207; called by muse, mutect2, varscan2
- SLC13A3 | c.1288A>T p.I430F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV51724201; called by mutect2, varscan2
- SLC33A1 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV63947823; called by muse, mutect2, varscan2
- SLC36A2 | c.565T>C p.S189P | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV58865458; called by muse, mutect2, varscan2
- SLC4A2 | c.3661G>A p.A1221T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as COSV52542587; called by muse, mutect2, varscan2
- SLC9A2 | c.1360T>C p.F454L | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1443843603, COSV52138726; called by muse, mutect2, varscan2
- SLC9A4 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54840102; called by muse, mutect2, varscan2
- SLC9C1 | c.2678G>T p.C893F | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs1305188371, COSV59894413; called by muse, mutect2, varscan2
- SLK | c.2167A>G p.K723E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV59829577; called by muse, mutect2, varscan2
- SORD | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as COSV51045525; called by muse, mutect2, varscan2
- SPAG17 | c.4202A>C p.N1401T | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60469927; called by muse, mutect2, varscan2
- SPI1 | c.613C>G p.H205D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57034662; called by muse, mutect2, varscan2
- SPINK6 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV57779219; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen benign (0.009); catalogued as COSV56572875; called by muse, mutect2, varscan2
- STAT4 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV61832858; called by muse, mutect2, varscan2
- STX19 | c.853T>G p.C285G | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57402380; called by muse, mutect2
- SUPT3H | c.958A>T p.R320W (on ENST00000371460 / NM_181356.3; = p.R309W on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60953456; called by muse, mutect2, varscan2
- SYCP2 | c.830+2T>C p.X277_splice | Splice Site (SNP) | VAF 20/119 reads (17%) | catalogued as COSV62773205; called by muse, mutect2, varscan2
- SYNE1 | c.5297A>G p.E1766G (on ENST00000367255 / NM_182961.4; = p.E1773G on NM_033071.3) | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV54919926; called by muse, mutect2
- SYNGR4 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV61226161; called by muse, mutect2, varscan2
- SYT9 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as rs773098666, COSV59617513; called by muse, mutect2, varscan2
- TACR1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.364); catalogued as COSV59486696; called by muse, mutect2, varscan2
- TCF20 | c.4954G>C p.A1652P | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59496775; called by muse, mutect2, varscan2
- TCFL5 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1302597823, COSV53899485; called by muse, mutect2, varscan2
- TEX55 | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.736); catalogued as COSV55210558; called by muse, mutect2, varscan2
- THBD | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV65703298; called by muse, mutect2
- TIAM1 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54578048; called by muse, mutect2, varscan2
- TMEM52B | c.184T>C p.S62P (on ENST00000381923 / NM_001079815.1; = p.S42P on NM_153022.4) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs779133035, COSV53729932; called by muse, mutect2, varscan2
- TRAPPC8 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV51971302; called by muse, mutect2, varscan2
- TRHDE | c.1653A>G p.Q551= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV53869300; called by muse, mutect2, varscan2
- TRPV4 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55686316; called by muse, mutect2, varscan2
- TSSC4 | c.515A>C p.E172A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV50210572; called by muse, mutect2
- TTN | c.28673G>T p.R9558M (on ENST00000591111; = p.R8631M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/235 reads (13%) | PolyPhen benign (0.413); catalogued as COSV60392950; called by muse, mutect2, varscan2
- TTN | c.2590G>A p.V864M (on ENST00000591111; = p.V818M on NM_003319.4) | Missense Mutation (SNP) | VAF 62/228 reads (27%) | PolyPhen benign (0.406); catalogued as rs375659512; called by muse, varscan2
- TUBA1A | c.1274T>C p.M425T | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as CM103942, COSV55499075; called by muse, mutect2, varscan2
- TUBA3C | c.148A>G p.N50D | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV67140175; called by muse, mutect2, varscan2
- UBA1 | c.1228A>G p.M410V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV60115930; called by muse, mutect2, varscan2
- UBE4A | c.3029C>T p.S1010F (on ENST00000252108 / NM_001204077.2; = p.S1017F on NM_004788.4) | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52807305; called by muse, mutect2, varscan2
- UFL1 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65150820; called by muse, mutect2, varscan2
- USH2A | c.6553C>A p.H2185N | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV56448944; called by muse, mutect2
- USP20 | c.1477T>C p.Y493H | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59619969; called by muse, mutect2
- USP53 | c.1936A>T p.M646L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56798272; called by muse, mutect2, varscan2
- VAT1L | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56829856; called by muse, mutect2, varscan2
- VPS13C | c.6479C>T p.P2160L (on ENST00000644861 / NM_020821.3; = p.P2117L on NM_017684.5) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV51428118; called by muse, mutect2, varscan2
- VPS45 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.897); catalogued as COSV64889322; called by muse, mutect2
- VPS50 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1272584037, COSV52492528, COSV52497528; called by muse, mutect2, varscan2
- VPS52 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.929); catalogued as COSV71403653; called by muse, mutect2, varscan2
- VWA5A | c.2314A>T p.I772F | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV64414857; called by muse, mutect2, varscan2
- WDR87 | c.3233C>T p.P1078L | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as COSV58208030; called by muse, mutect2, varscan2
- WNT8A | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.392); catalogued as COSV64231859; called by muse, mutect2, varscan2
- ZC3H18 | c.224A>C p.E75A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.37); catalogued as COSV56328535; called by muse, mutect2, varscan2
- ZC3H6 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV59670967; called by muse, varscan2
- ZFP2 | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.268); catalogued as rs766251937, COSV63727206; called by mutect2, varscan2
- ZFP30 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV63622501, COSV63623226; called by muse, mutect2, varscan2
- ZHX3 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58389320; called by muse, mutect2, varscan2
- ZNF135 | c.1061A>T p.Y354F (on ENST00000313434 / NM_001289401.2; = p.Y366F on NM_003436.4) | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.673); catalogued as COSV57886625; called by muse, mutect2, varscan2
- ZNF222 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs773301920, COSV51828771; called by muse, mutect2, varscan2
- ZNF280C | c.1831A>T p.N611Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV63970104; called by muse, mutect2, varscan2
- ZNF426 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53470113; called by muse, mutect2, varscan2
- ZNF439 | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV58311362; called by muse, mutect2, varscan2
- ZNF518B | c.2492G>A p.G831E | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58725115; called by muse, mutect2, varscan2
- ZNF578 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV69736540, COSV69736542; called by muse, mutect2, varscan2
- ZNF714 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs371085101, COSV52516227; called by muse, mutect2, varscan2
- ZNF821 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57988472; called by muse, varscan2
- ZNHIT6 | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs139368369; called by muse, mutect2, varscan2
- AP4E1 | c.3124G>A p.G1042R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1B | c.1881del p.M628Cfs*33 | Frame Shift Del (DEL) | VAF 54/180 reads (30%) | called by mutect2, pindel, varscan2
- CADPS | c.2033A>T p.H678L | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CADPS | c.2032C>A p.H678N | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ERVW-1 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.243); called by muse, mutect2
- HERC2 | c.7846G>T p.G2616C | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, varscan2
- IGKV1D-8 | c.257del p.G86Afs*? | Frame Shift Del (DEL) | VAF 161/342 reads (47%) | called by mutect2, pindel, varscan2
- MUC19 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NIBAN1 | c.2477A>G p.E826G | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- OAZ3 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2
- PKHD1L1 | c.664del p.S222Lfs*20 | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | called by mutect2, pindel, varscan2
- POU3F2 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PRKCB | c.1728del p.M576Ifs*66 (on ENST00000321728 / NM_212535.3; = p.M576Ifs*65 on NM_002738.7) | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- RPS9 | c.160del p.R54Afs*8 | Frame Shift Del (DEL) | VAF 31/124 reads (25%) | called by mutect2, pindel, varscan2
- SEMA6A | c.108del p.K36Nfs*25 | Frame Shift Del (DEL) | VAF 87/281 reads (31%) | called by mutect2, varscan2
- SLITRK3 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, mutect2
- A2M | c.1101G>A p.G367= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV59393515; called by muse, mutect2, varscan2
- ACE | c.3454C>T p.L1152= | Silent (SNP) | VAF 184/300 reads (61%) | catalogued as COSV52014048; called by muse, mutect2, varscan2
- ADGRF5 | c.3921T>C p.S1307= | Silent (SNP) | VAF 67/498 reads (13%) | catalogued as COSV51941371; called by muse, mutect2, varscan2
- AFF3 | c.2850G>A p.T950= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as rs762823547, COSV57851841; called by muse, mutect2, varscan2
- ANKRA2 | c.381A>G p.K127= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as COSV57142025; called by muse, mutect2, varscan2
- ANKRD30A | c.3357C>T p.A1119= (on ENST00000611781; = p.A1063= on NM_052997.2) | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as COSV64609532; called by muse, mutect2, varscan2
- ARFGEF3 | c.5583C>T p.D1861= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV52472615; called by muse, mutect2, varscan2
- ARL5C | c.99C>T p.L33= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV54096318; called by muse, mutect2, varscan2
- ARMH1 | c.303G>A p.E101= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV62638267; called by muse, mutect2, varscan2
- ASB5 | c.183A>G p.V61= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV56674884; called by muse, mutect2, varscan2
- BAHCC1 | c.5052G>T p.V1684= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57034353; called by mutect2, varscan2
- BMT2 | c.57G>A p.P19= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1212289406, COSV51781571; called by muse, mutect2
- BRPF1 | c.465G>A p.E155= | Silent (SNP) | VAF 34/197 reads (17%) | catalogued as rs1238620393, COSV57408520; called by muse, mutect2, varscan2
- C1R | c.342G>C p.P114= (on ENST00000536053 / NM_001354346.2; = p.P100= on NM_001733.7) | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV56926620, COSV56927021; called by muse, mutect2, varscan2
- C1orf94 | c.1386C>T p.L462= (on ENST00000488417 / NM_001134734.2; = p.L272= on NM_032884.5) | Silent (SNP) | VAF 42/189 reads (22%) | catalogued as COSV64916060; called by muse, mutect2, varscan2
- CACNA1E | c.3444C>T p.Y1148= | Silent (SNP) | VAF 25/234 reads (11%) | catalogued as COSV62433721; called by muse, mutect2, varscan2
- CASP8AP2 | c.5802C>T p.D1934= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs1319584033, COSV52750391; called by muse, mutect2, varscan2
- CATSPERD | c.1527C>G p.G509= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as COSV58467899; called by muse, mutect2, varscan2
- CCDC142 | c.1485G>A p.K495= (on ENST00000393965 / NM_001365575.2; = p.K488= on NM_032779.4) | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as COSV51780249, COSV99281988; called by muse, mutect2, varscan2
- CCDC22 | c.795C>T p.A265= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV66052120; called by muse, mutect2, varscan2
- CCDC34 | c.156G>T p.S52= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV58727316; called by muse, mutect2
- CEP250 | c.4144A>C p.R1382= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs151254784; called by muse, mutect2, varscan2
- CFAP43 | c.1446T>C p.Y482= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV53381959; called by muse, mutect2, varscan2
- CHRM5 | c.1554A>G p.K518= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs778538576, COSV67248851; called by muse, mutect2, varscan2
- CHRNB2 | c.405C>T p.A135= | Silent (SNP) | VAF 24/235 reads (10%) | catalogued as rs777250519, COSV63809602; called by muse, mutect2
- CLASRP | c.51C>T p.V17= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs757003701, COSV55513349; called by muse, mutect2
- CLDN12 | c.156A>G p.T52= | Silent (SNP) | VAF 31/239 reads (13%) | catalogued as COSV55308325; called by muse, mutect2, varscan2
- COBLL1 | c.3484C>T p.L1162= (on ENST00000392717; = p.L1124= on NM_014900.5) | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV52077497; called by muse, mutect2, varscan2
- CYP11B2 | c.1038C>T p.A346= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs200388238, COSV59998210; called by muse, mutect2, varscan2
- CYSLTR1 | c.1011A>G p.V337= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV64821426; called by muse, mutect2, varscan2
- DIP2A | c.933G>A p.K311= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV59488370; called by muse, mutect2, varscan2
- DNAAF4 | c.345A>T p.T115= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as COSV58252025; called by muse, mutect2, varscan2
- DNHD1 | c.8901T>C p.P2967= | Silent (SNP) | VAF 62/128 reads (48%) | catalogued as COSV54444243; called by muse, mutect2, varscan2
- ENTPD1 | c.1413T>C p.P471= | Silent (SNP) | VAF 80/610 reads (13%) | catalogued as COSV64604810; called by muse, mutect2, varscan2
- FAM47A | c.93G>A p.A31= | Silent (SNP) | VAF 36/257 reads (14%) | catalogued as COSV60495298; called by muse, mutect2, varscan2
- FAM71E2 | c.1092C>T p.P364= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV52774119; called by muse, mutect2, varscan2
- FAT2 | c.3174C>T p.D1058= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs542235186, COSV55831156; called by muse, mutect2, varscan2
- FCRL5 | c.2094C>T p.V698= | Silent (SNP) | VAF 37/392 reads (9%) | catalogued as rs776474306, COSV62521061; called by muse, mutect2
- FEM1A | c.1929G>A p.A643= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1411747272, COSV54165069; called by muse, mutect2, varscan2
- FLG | c.585C>T p.D195= | Silent (SNP) | VAF 32/282 reads (11%) | catalogued as rs375267392, COSV64251203; called by muse, mutect2
- FRMD7 | c.2025C>T p.A675= | Silent (SNP) | VAF 47/328 reads (14%) | catalogued as COSV53749394; called by muse, mutect2, varscan2
- FRYL | c.783A>T p.I261= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV51964268; called by muse, mutect2, varscan2
- GABRA4 | c.1119T>A p.P373= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV51936290; called by muse, mutect2, varscan2
- GABRB3 | c.1227A>G p.R409= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV54686742; called by muse, mutect2, varscan2
- GABRR3 | c.7C>T p.L3= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV72084425; called by muse, mutect2, varscan2
- GATAD2B | c.1254T>C p.F418= | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as COSV64086459; called by muse, mutect2
- GIGYF2 | c.3444G>A p.T1148= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV65254003; called by muse, mutect2, varscan2
- GP1BA | c.1134C>A p.S378= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as COSV56701051; called by muse, mutect2, varscan2
- GPM6B | c.285G>A p.A95= | Silent (SNP) | VAF 28/196 reads (14%) | catalogued as rs759835302, COSV57423296; called by muse, mutect2, varscan2
- GPX6 | c.426A>T p.G142= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV62659298; called by muse, mutect2
- GRIN2A | c.2457C>T p.G819= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs750219908, COSV58046550; called by mutect2, varscan2
- GRM1 | c.3244C>T p.L1082= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV51371393; called by muse, mutect2
- GRM7 | c.2229C>T p.A743= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as COSV63175464; called by muse, mutect2, varscan2
- GTF3C1 | c.2427C>T p.Y809= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV62245552; called by muse, varscan2
- HERC2 | c.7845G>T p.G2615= | Silent (SNP) | VAF 66/366 reads (18%) | called by muse, varscan2
- HMCN1 | c.10953T>A p.P3651= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV54946950; called by muse, mutect2, varscan2
- HTR1F | c.804C>T p.L268= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV60391473; called by muse, mutect2, varscan2
- IGF1R | c.1263C>T p.Y421= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs542546475, COSV51403636; called by muse, mutect2
- IL1RL1 | c.1518A>G p.V506= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as COSV52121278; called by muse, mutect2
- IQSEC3 | c.2199G>A p.E733= (on ENST00000538872 / NM_001170738.2; = p.E430= on NM_015232.1) | Silent (SNP) | VAF 54/198 reads (27%) | catalogued as COSV58292012; called by muse, mutect2, varscan2
- ITGAX | c.2793C>T p.H931= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs985017935, COSV51652426; called by muse, mutect2, varscan2
- KCNJ2 | c.645C>T p.G215= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV54664274; called by muse, mutect2, varscan2
- KCNK13 | c.1087C>T p.L363= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV56412685, COSV99965532; called by muse, mutect2, varscan2
- KLF12 | c.747C>A p.T249= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as COSV66582889; called by muse, mutect2, varscan2
- KLK9 | c.679A>C p.R227= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV51595062; called by muse, mutect2, varscan2
- KNDC1 | c.5043G>A p.Q1681= | Silent (SNP) | VAF 33/280 reads (12%) | catalogued as COSV58847523; called by muse, mutect2, varscan2
- KRTAP5-3 | c.105C>T p.C35= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs371318576; called by muse, mutect2, varscan2
- LEPR | c.2982A>G p.K994= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV62752730; called by muse, mutect2, varscan2
- LHCGR | c.1698G>A p.K566= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as rs1165348987, COSV54296798; called by muse, mutect2
- LRRK1 | c.3660T>A p.P1220= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV52628098; called by muse, mutect2
- MAGEB6 | c.339C>A p.G113= | Silent (SNP) | VAF 57/205 reads (28%) | catalogued as COSV66873291; called by muse, mutect2, varscan2
- MICAL3 | c.2580G>A p.V860= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV52906496; called by muse, mutect2, varscan2
- MMP1 | c.1125G>A p.K375= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV59512103; called by muse, mutect2, varscan2
- MUC4 | c.11163A>G p.V3721= | Silent (SNP) | VAF 49/464 reads (11%) | catalogued as rs1481873047, COSV57806124; called by muse, mutect2
- NOS3 | c.1266C>T p.A422= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs534664057, COSV52496708; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOTCH4 | c.1050A>T p.T350= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV66684441; called by muse, mutect2
- NRK | c.3534A>G p.S1178= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV54608592; called by muse, mutect2, varscan2
- NUTM2F | c.1344T>C p.C448= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs779690174, COSV53560788; called by muse, mutect2, varscan2
- OPCML | c.825A>G p.K275= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV59454673; called by muse, mutect2, varscan2
- OR10A5 | c.666T>C p.I222= | Silent (SNP) | VAF 49/425 reads (12%) | catalogued as COSV55055914; called by muse, mutect2, varscan2
- OR4A5 | c.312C>T p.F104= | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as rs866826742, COSV60521518; called by muse, mutect2, varscan2
- PDC | c.573C>A p.I191= | Silent (SNP) | VAF 13/163 reads (8%) | catalogued as COSV60854933; called by muse, mutect2
- PDHA1 | c.489C>T p.G163= | Silent (SNP) | VAF 49/289 reads (17%) | catalogued as rs1555933962, COSV63329213; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1 | c.2073C>T p.L691= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV61897444; called by muse, mutect2
- PLCB3 | c.2160G>A p.V720= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1049791374, COSV54186281; called by muse, mutect2
- PLCE1 | c.957G>A p.K319= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV53374925; called by muse, mutect2
- POU3F2 | c.1158C>A p.S386= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV100099270, COSV60409393; called by muse, mutect2, varscan2
- PTGR1 | c.276A>T p.T92= | Silent (SNP) | VAF 38/206 reads (18%) | catalogued as COSV53031215; called by muse, mutect2, varscan2
- PTPRQ | c.5613A>G p.T1871= (on ENST00000616559; = p.T1829= on NM_001145026.2) | Silent (SNP) | VAF 52/179 reads (29%) | catalogued as COSV57056482; called by muse, mutect2, varscan2
- RBM19 | c.2568G>A p.G856= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV55699732; called by muse, mutect2, varscan2
- RBMX | c.801T>C p.G267= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV57811792; called by muse, mutect2, varscan2
- RIBC2 | c.198A>G p.R66= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV61582418; called by muse, mutect2, varscan2
- RNF146 | c.72C>T p.S24= (on ENST00000368314 / NM_001242850.2; = p.S23= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/301 reads (11%) | catalogued as COSV58934564; called by muse, mutect2, varscan2
- SASH1 | c.1182G>A p.K394= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV66566705; called by muse, mutect2
- SEC16A | c.3891T>C p.Y1297= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV51542332; called by muse, mutect2, varscan2
- SEC24B | c.2284C>T p.L762= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV54507738; called by muse, mutect2, varscan2
- SETDB1 | c.810T>C p.D270= | Silent (SNP) | VAF 36/385 reads (9%) | catalogued as COSV54993538; called by muse, mutect2
- SLC9A4 | c.1269C>A p.I423= | Silent (SNP) | VAF 57/384 reads (15%) | catalogued as COSV54837673; called by muse, mutect2, varscan2
- SLIT1 | c.3594G>A p.E1198= | Silent (SNP) | VAF 56/309 reads (18%) | catalogued as COSV56585452, COSV99821201; called by muse, mutect2, varscan2
- SPIN4 | c.621T>C p.H207= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as COSV58738730; called by muse, mutect2, varscan2
- TDRD5 | c.2751T>C p.A917= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV54251469; called by muse, mutect2
- TEK | c.810A>G p.G270= | Silent (SNP) | VAF 42/220 reads (19%) | catalogued as rs1055114133, COSV66235770; called by muse, mutect2, varscan2
- TIMM50 | c.984G>A p.E328= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as COSV58680961; called by muse, mutect2, varscan2
- TLL1 | c.1650T>C p.N550= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs766550068, COSV50334003; called by muse, mutect2, varscan2
- TMEM135 | c.321G>A p.L107= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV59707467; called by muse, mutect2, varscan2
- TNNT3 | c.276C>A p.A92= (on ENST00000397301 / NM_001367846.1; = p.A81= on NM_006757.4) | Silent (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2, varscan2
- TNNT3 | c.277C>A p.R93= (on ENST00000397301 / NM_001367846.1; = p.R82= on NM_006757.4) | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as rs193178655; called by muse, mutect2, varscan2
- TREML4 | c.177T>C p.S59= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV58386647; called by muse, mutect2, varscan2
- UBASH3B | c.783C>T p.V261= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV52503586; called by muse, mutect2, varscan2
- ZNF441 | c.102G>A p.Q34= | Silent (SNP) | VAF 19/192 reads (10%) | catalogued as COSV63540960; called by muse, mutect2
- ZNF608 | c.3066T>C p.S1022= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1178526662, COSV60441961; called by muse, mutect2, varscan2
- AMER3 | c.*596T>A | 3'UTR (SNP) | VAF 57/253 reads (23%) | catalogued as COSV100366255; called by muse, mutect2, varscan2
- ARHGAP24 | c.391+7211A>T | Intron (SNP) | VAF 19/86 reads (22%) | catalogued as COSV51994445; called by muse, mutect2, varscan2
- CHAMP1 | c.*430T>A | 3'UTR (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100778761; called by muse, mutect2
- CHRM3 | c.*5435T>C | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- COL12A1 | c.-11G>A | 5'UTR (SNP) | VAF 15/69 reads (22%) | catalogued as rs745772474, COSV100485173; called by muse, mutect2, varscan2
- DMRTC2 | c.-1C>A | 5'UTR (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99523346; called by muse, mutect2, varscan2
- FAM184A | c.159+9063A>C | Intron (SNP) | VAF 35/306 reads (11%) | catalogued as COSV58859301; called by muse, mutect2, varscan2
- FOXC1 | c.*1119G>A | 3'UTR (SNP) | VAF 10/110 reads (9%) | catalogued as COSV101083262; called by muse, mutect2
- GGCX | c.374-26C>T | Intron (SNP) | VAF 69/242 reads (29%) | called by muse, mutect2, varscan2
- H2BC12 | c.-19C>T | 5'UTR (SNP) | VAF 70/189 reads (37%) | catalogued as rs1362418814; called by muse, mutect2, varscan2
- HERC2P3 | n.459G>A | RNA (SNP) | VAF 6/46 reads (13%) | catalogued as rs528953010; called by mutect2, varscan2
- MAGEA4 | c.*198A>G | 3'UTR (SNP) | VAF 36/190 reads (19%) | catalogued as rs1169191655, COSV99367404; called by muse, mutect2, varscan2
- MC4R | c.-363T>A | 5'UTR (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100235930; called by muse, mutect2, varscan2
- MFAP3 | c.*159A>G | 3'UTR (SNP) | VAF 14/102 reads (14%) | catalogued as COSV100491554; called by muse, mutect2, varscan2
- MIR206 | n.67G>A | RNA (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- MIR525 | n.32T>A | RNA (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- MUCL3 | c.946+1113C>A | Intron (SNP) | VAF 30/194 reads (15%) | catalogued as COSV58519239; called by muse, varscan2
- NPAP1 | c.*2773C>T | 3'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100275039; called by muse, mutect2, varscan2
- NRG2 | c.1190-4125G>A | Intron (SNP) | VAF 29/222 reads (13%) | catalogued as rs751821744, COSV56841439; called by muse, mutect2, varscan2
- PCDHGA11 | c.2433+82A>T | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7716A>G | Intron (SNP) | VAF 9/141 reads (6%) | catalogued as rs1553492821, COSV57733147; called by muse, mutect2
- PHETA2 | c.*655T>A | 3'UTR (SNP) | VAF 35/227 reads (15%) | catalogued as COSV100408904; called by muse, mutect2, varscan2
- PIPSL | n.2005G>A | RNA (SNP) | VAF 39/311 reads (13%) | called by muse, mutect2, varscan2
- PSMB7 | c.-1G>C | 5'UTR (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99412789; called by muse, mutect2
- RBMXL2 | c.*514A>G | 3'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100182159; called by muse, mutect2
- RMI1 | c.*1085A>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs945970475, COSV100366118; called by muse, mutect2
- SLC66A1L | n.443+6269C>T | Intron (SNP) | VAF 68/219 reads (31%) | catalogued as COSV56600730; called by muse, varscan2
- SMAP1 | c.664+830C>T | Intron (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.1187A>T | RNA (SNP) | VAF 52/243 reads (21%) | called by muse, mutect2, varscan2
- TET2 | c.3501-418A>G | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99481990; called by muse, mutect2, varscan2
- TSHZ1 | c.*1118T>G | 3'UTR (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100433502; called by muse, mutect2, varscan2
- TTN | c.10360+1482A>T | Intron (SNP) | VAF 29/113 reads (26%) | catalogued as COSV60392965; called by muse, mutect2, varscan2
- USP27X | c.*353A>G | 3'UTR (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101455279; called by muse, mutect2, varscan2
- ZSCAN18 | c.49+11T>C | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs1002756431; called by muse, mutect2
